FM case AD14516 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas.
https://portal.gdc.cancer.gov/cases/0a58fe5c-48e6-4623-aec3-11011e639631

Male, 65.3 years: Adenocarcinoma, NOS (ICD-O-3 8140/3); specimen biopsied or resected from the specified parts of peritoneum. Tumor nuclei on the sequenced sample's slide: 25% (pathologist estimate recorded by GDC). Sample type: Tumor.
